Somatic mutation profile of tumor specimen TCGA-85-7699-01A (aliquot TCGA-85-7699-01A-11D-2122-08) from TCGA case TCGA-85-7699, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 73.8 years (26,965 days).
Specimen TCGA-85-7699-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e34bfeb-a7a4-4dca-b888-41c4f9f7e924.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-7699-10A (Blood Derived Normal), aliquot TCGA-85-7699-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c701d54c-8707-46ab-905c-df1f646314fe

The open-access MAF lists 188 somatic variants for this specimen: 142 protein-altering or splice-affecting, 39 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 39, Splice Site 10, Nonsense Mutation 7, Frame Shift Del 6, Intron 2, Splice Region 2, RNA 2, 5'Flank 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | hotspot (GDC flag); catalogued as rs1057519852, COSV58682976, COSV58690849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 30/111 reads (27%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 34/131 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB10 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.241); catalogued as rs144276366, COSV100747871; called by muse, mutect2, varscan2
- ABHD11 | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV99766716; called by muse, mutect2, varscan2
- ADAM22 | c.1392+1G>A p.X464_splice | Splice Site (SNP) | VAF 44/109 reads (40%) | catalogued as rs1563319371, COSV99716135; called by muse, mutect2, varscan2
- ADAMTS20 | c.1258A>G p.K420E | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs765887467, COSV101239048; called by muse, mutect2, varscan2
- ADAMTS7 | c.3446C>G p.P1149R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.483); catalogued as COSV101183043; called by muse, mutect2, varscan2
- AHCTF1 | c.6504A>T p.K2168N (on ENST00000366508; = p.K2142N on NM_015446.5) | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs796550402, COSV100403311; called by muse, mutect2, varscan2
- AHCTF1 | c.3878C>T p.P1293L (on ENST00000366508; = p.P1267L on NM_015446.5) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs201984673, COSV100403313; called by muse, mutect2, varscan2
- ANK2 | c.4894G>T p.D1632Y | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52175040; called by muse, mutect2, varscan2
- APEX1 | c.82A>T p.T28S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99164453; called by muse, mutect2, varscan2
- APOB | c.5305A>G p.K1769E | Missense Mutation (SNP) | VAF 194/325 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99264324; called by muse, mutect2, varscan2
- AWAT2 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99339576; called by muse, mutect2, varscan2
- AXIN1 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as COSV99249440; called by muse, mutect2
- BBS9 | c.2642C>G p.P881R (on ENST00000242067 / NM_001348036.1; = p.P841R on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.203); catalogued as rs756620095, COSV54161977, COSV99626736; called by muse, mutect2, varscan2
- BCHE | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100012241; called by muse, mutect2, varscan2
- BCR | c.3211G>T p.V1071L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100006125; called by muse, mutect2, varscan2
- BRCA2 | c.5096A>G p.D1699G | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as rs80358732, COSV101204009; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C10orf71 | c.857A>T p.K286M | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100109848; called by muse, mutect2, varscan2
- C6orf58 | c.701C>A p.A234E | Missense Mutation (SNP) | VAF 85/249 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.595); catalogued as COSV100314770, COSV61667508; called by muse, mutect2, varscan2
- CCDC110 | c.1631A>G p.D544G | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV100293744; called by muse, mutect2, varscan2
- CCDC190 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100905809; called by muse, mutect2, varscan2
- CCN3 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV99422797; called by muse, mutect2, varscan2
- CDCA2 | c.3026T>C p.L1009P | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as rs533786348, COSV100398781; called by muse, mutect2, varscan2
- CELF4 | c.388G>C p.V130L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100611282, COSV58451355; called by muse, mutect2, varscan2
- CERS3 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1178676096, COSV99431514; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CIT | c.1333A>T p.S445C | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.227); catalogued as COSV99948825; called by muse, mutect2, varscan2
- CLEC4D | c.493C>A p.R165S | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100222924, COSV55227887; called by muse, mutect2, varscan2
- CNTNAP5 | c.432G>C p.L144F | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV101443146, COSV70486304, COSV99081552; called by muse, mutect2
- COL13A1 | c.1883G>A p.G628D (on ENST00000398978 / NM_001130103.2; = p.G556D on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100637341; called by muse, mutect2, varscan2
- COL3A1 | c.3661G>A p.G1221R | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV100482677; called by muse, mutect2, varscan2
- COL4A4 | c.1661G>A p.G554E | Missense Mutation (SNP) | VAF 95/264 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100306418; called by muse, mutect2, varscan2
- CPED1 | c.2868+2T>A p.X956_splice | Splice Site (SNP) | VAF 74/248 reads (30%) | catalogued as COSV100120296; called by muse, mutect2, varscan2
- CSMD3 | c.2281C>A p.L761I (on ENST00000297405 / NM_001363185.1; = p.L657I on NM_052900.3) | Missense Mutation (SNP) | VAF 51/270 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV52129362, COSV99828094, COSV99841759; called by muse, mutect2, varscan2
- DAW1 | c.543G>A p.V181= | Splice Region (SNP) | VAF 32/84 reads (38%) | catalogued as rs1190347222, COSV100005992; called by muse, mutect2, varscan2
- DCC | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 74/268 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs780738407, COSV59095079, COSV59142839; called by muse, mutect2, varscan2
- DDI1 | c.1064G>C p.G355A | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100158269; called by muse, mutect2, varscan2
- DGKI | c.776A>T p.Q259L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99932953; called by muse, mutect2, varscan2
- DNAJC13 | c.6212G>A p.R2071Q | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as rs771909946, COSV99606835; called by muse, mutect2, varscan2
- DPPA4 | c.607C>A p.L203M | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV100169280; called by muse, mutect2, varscan2
- EDC3 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100165831; called by muse, mutect2, varscan2
- EIF4G2 | c.866A>T p.E289V | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100379423; called by muse, mutect2, varscan2
- ENPP2 | c.1349G>T p.R450L (on ENST00000075322 / NM_001040092.3; = p.R502L on NM_006209.5) | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs747849078, COSV50011509, COSV99307771; called by muse, mutect2, varscan2
- EP300 | c.9G>T p.E3D | Missense Mutation (SNP) | VAF 89/357 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.376); catalogued as COSV99607764; called by muse, mutect2, varscan2
- F10 | c.1011C>A p.N337K | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs763538411, COSV100979159; called by muse, mutect2, varscan2
- FLRT3 | c.1040A>T p.D347V | Missense Mutation (SNP) | VAF 80/251 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV99428541; called by muse, mutect2, varscan2
- FRMPD4 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 85/143 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66213848; called by muse, varscan2
- FRMPD4 | c.2527G>A p.D843N | Missense Mutation (SNP) | VAF 71/113 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs1308469382, COSV101042387, COSV66224629; called by muse, varscan2
- GRB10 | c.1095G>T p.K365N (on ENST00000398812; = p.K319N on NM_001001549.3) | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757062459, COSV100239941; called by muse, mutect2, varscan2
- GRIN2B | c.4010C>T p.A1337V | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV101662954; called by muse, mutect2, varscan2
- GRM6 | c.1346G>T p.R449L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99179494; called by muse, mutect2, varscan2
- HGF | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99736014; called by muse, mutect2, varscan2
- HSP90AB1 | c.634C>G p.P212A | Missense Mutation (SNP) | VAF 63/498 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100806990; called by muse, mutect2, varscan2
- INSRR | c.2012G>T p.R671L | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.675); catalogued as COSV100947260; called by muse, mutect2, varscan2
- ITK | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV101439664; called by muse, mutect2, varscan2
- LAMA2 | c.1774G>T p.G592* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV101370236, COSV70352367; called by muse, mutect2, varscan2
- LCTL | c.1592C>A p.P531H | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100328498; called by muse, mutect2, varscan2
- LILRA6 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 40/466 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs201828111; called by muse, mutect2
- LILRB4 | c.73C>G p.P25A | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0.019); catalogued as COSV99553586; called by muse, mutect2, varscan2
- LRFN5 | c.455T>A p.L152Q | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99982872; called by muse, mutect2, varscan2
- LRP2 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV99787081; called by muse, mutect2, varscan2
- LRRK2 | c.462T>A p.D154E | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100109510; called by muse, mutect2, varscan2
- LTBP3 | c.2663G>A p.G888D | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99533887; called by muse, mutect2
- MET | c.140C>G p.T47S | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.429); catalogued as COSV100577075; called by muse, mutect2, varscan2
- MLNR | c.1083G>C p.K361N | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV99519725; called by muse, mutect2, varscan2
- MPL | c.1760C>A p.A587D | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV100991406; called by muse, mutect2, varscan2
- MST1 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as rs1225484117, COSV99610602; called by muse, mutect2, varscan2
- MYOCD | c.2208G>C p.Q736H | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100590333; called by muse, mutect2, varscan2
- NALCN | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 114/387 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV51933965, COSV99213542; called by muse, mutect2, varscan2
- NCAM2 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1452720475, COSV99521852; called by muse, mutect2, varscan2
- NCAM2 | c.1195+1G>A p.X399_splice | Splice Site (SNP) | VAF 35/143 reads (24%) | catalogued as COSV99521854; called by muse, mutect2, varscan2
- NECTIN4 | c.952A>T p.S318C | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1038881167, COSV100919845; called by muse, mutect2, varscan2
- NLRP7 | c.2875C>G p.P959A (on ENST00000340844 / NM_206828.3; = p.P988A on NM_139176.3) | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100051859; called by muse, mutect2, varscan2
- NOVA1 | c.299G>T p.C100F | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV99946794; called by muse, mutect2, varscan2
- NR1H3 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100211175; called by muse, mutect2, varscan2
- NUDCD1 | c.1300-1G>T p.X434_splice | Splice Site (SNP) | VAF 18/93 reads (19%) | catalogued as COSV99516825; called by muse, mutect2, varscan2
- NUTM2D | c.65A>G p.E22G | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.727); catalogued as COSV101096871; called by muse, mutect2, varscan2
- OR10R2 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100936767; called by muse, mutect2, varscan2
- OR4D6 | c.428C>A p.A143D | Missense Mutation (SNP) | VAF 127/343 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.356); catalogued as COSV100271601; called by muse, mutect2, varscan2
- OR4K17 | c.491T>A p.V164E | Missense Mutation (SNP) | VAF 12/351 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100210561; called by muse, mutect2
- OR4P4 | c.82T>A p.L28I | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV100111613; called by muse, mutect2, varscan2
- OR5B2 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100222810; called by muse, mutect2, varscan2
- OR5I1 | c.835T>C p.F279L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100041271; called by muse, mutect2, varscan2
- PCDHA1 | c.1637G>C p.G546A | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.082); catalogued as COSV100974309; called by muse, mutect2, varscan2
- PDE4DIP | c.4397G>C p.R1466T | Missense Mutation (SNP) | VAF 65/350 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100517545; called by muse, mutect2, varscan2
- PHACTR2 | c.1556+1G>A p.X519_splice | Splice Site (SNP) | VAF 44/145 reads (30%) | catalogued as COSV99991174; called by muse, mutect2, varscan2
- PIK3R5 | c.811+1G>A p.X271_splice | Splice Site (SNP) | VAF 32/135 reads (24%) | catalogued as COSV99353031; called by muse, mutect2, varscan2
- PIWIL3 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 72/237 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs139495727; called by muse, varscan2
- PKHD1L1 | c.4184C>T p.T1395I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV101005654; called by muse, mutect2, varscan2
- PLPPR1 | c.597A>T p.K199N | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100883123; called by muse, mutect2, varscan2
- PRKD1 | c.2242G>T p.A748S | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100119516, COSV59576052; called by muse, mutect2, varscan2
- PRUNE2 | c.6337G>A p.A2113T | Missense Mutation (SNP) | VAF 57/265 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1564093692, COSV100944302; called by muse, mutect2, varscan2
- RALYL | c.220G>T p.G74* | Nonsense Mutation (SNP) | VAF 29/91 reads (32%) | catalogued as COSV101569078; called by muse, mutect2, varscan2
- RBM46 | c.1178C>G p.S393C | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV55977531, COSV99907950, COSV99908156; called by muse, mutect2, varscan2
- RSPH6A | c.1478A>T p.Q493L | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99679637; called by muse, mutect2, varscan2
- RYR2 | c.7827G>T p.L2609= | Splice Region (SNP) | VAF 39/150 reads (26%) | catalogued as COSV100768810; called by muse, mutect2, varscan2
- SCN10A | c.1126T>C p.F376L | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101479284; called by muse, mutect2, varscan2
- SETX | c.6064C>G p.L2022V | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.472); catalogued as COSV99809071; called by muse, mutect2, varscan2
- SLAIN1 | c.1523A>G p.N508S (on ENST00000466548; = p.N245S on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.188); catalogued as rs1312919547, COSV99935037; called by muse, mutect2, varscan2
- SLC13A4 | c.1738G>T p.D580Y | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62461466; called by muse, mutect2, varscan2
- SLC17A2 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV99613998; called by muse, mutect2, varscan2
- SLC35B2 | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99240976; called by muse, mutect2, varscan2
- SLC9A2 | c.1004+1G>A p.X335_splice | Splice Site (SNP) | VAF 79/223 reads (35%) | catalogued as rs759298686, COSV99295989; called by muse, mutect2, varscan2
- SNX9 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770275405, COSV101093887; called by muse, mutect2, varscan2
- SORCS1 | c.2635A>C p.S879R | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.142); catalogued as COSV53842076, COSV99544215; called by muse, mutect2, varscan2
- SWT1 | c.1969A>T p.K657* | Nonsense Mutation (SNP) | VAF 34/96 reads (35%) | catalogued as COSV100833136; called by muse, mutect2, varscan2
- SYNE1 | c.18420A>C p.L6140F (on ENST00000367255 / NM_182961.4; = p.L6069F on NM_033071.3) | Missense Mutation (SNP) | VAF 129/469 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99556595; called by muse, mutect2, varscan2
- TBL1XR1 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101467726; called by muse, mutect2, varscan2
- TENM3 | c.5497C>A p.Q1833K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.857); catalogued as COSV101304948; called by muse, mutect2, varscan2
- TLE2 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1212704038, COSV53584249; called by muse, mutect2, varscan2
- TLE4 | c.1333G>C p.G445R | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1299527427, COSV99511482; called by muse, mutect2, varscan2
- TMEM168 | c.1562G>T p.R521L | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as rs746902602, COSV100454531, COSV57180273; called by muse, varscan2
- TMEM199 | c.211+1G>T p.X71_splice | Splice Site (SNP) | VAF 38/109 reads (35%) | catalogued as COSV99134717; called by muse, mutect2, varscan2
- TNKS | c.3753C>A p.F1251L | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV100126434; called by muse, mutect2, varscan2
- TRIM37 | c.2803C>T p.P935S | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV99232467; called by muse, mutect2, varscan2
- TRIM51 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 104/271 reads (38%) | catalogued as COSV99792291; called by muse, mutect2, varscan2
- TRPM6 | c.3258C>G p.Y1086* | Nonsense Mutation (SNP) | VAF 8/232 reads (3%) | catalogued as COSV100665728; called by muse, mutect2
- TSHZ2 | c.1945G>T p.G649C | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs752310290, COSV100295564; called by muse, mutect2, varscan2
- TTN | c.19031T>C p.L6344S (on ENST00000591111; = p.L5417S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/294 reads (40%) | PolyPhen probably damaging (0.999); catalogued as rs772138264, COSV100600196; called by muse, mutect2, varscan2
- TUT1 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99545125; called by muse, mutect2, varscan2
- UNC13B | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.058); catalogued as COSV101036378; called by muse, mutect2
- XCR1 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1426821116, COSV58570042; called by muse, mutect2, varscan2
- ZBTB17 | c.230T>C p.M77T | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100998979; called by muse, mutect2
- ZNF226 | c.1514G>T p.C505F | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100335056; called by muse, mutect2, varscan2
- ZNF474 | c.206C>G p.S69* | Nonsense Mutation (SNP) | VAF 113/255 reads (44%) | catalogued as COSV56946344, COSV99682050; called by muse, mutect2, varscan2
- ZNF483 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 98/301 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs1192613215, COSV100492700; called by muse, mutect2, varscan2
- ZNF585A | c.935A>G p.Q312R (on ENST00000292841 / NM_001288800.2; = p.Q257R on NM_152655.3) | Missense Mutation (SNP) | VAF 142/626 reads (23%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.549); catalogued as COSV99492855; called by muse, mutect2, varscan2
- ZNF781 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.068); catalogued as rs777290854, COSV62201692; called by muse, mutect2, varscan2
- ZNF786 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 104/287 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); catalogued as COSV100302718; called by muse, mutect2, varscan2
- ZNF8 | c.200A>T p.E67V | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV99544170; called by muse, mutect2
- ZNF800 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.677); catalogued as COSV99757749; called by muse, mutect2, varscan2
- ZZEF1 | c.3189A>T p.E1063D | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV101067608; called by muse, mutect2, varscan2
- AXIN2 | c.2017A>T p.T673S | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CARMIL3 | c.1206_1217+9del p.X402_splice | Splice Site (DEL) | VAF 20/107 reads (19%) | called by mutect2, pindel, varscan2
- CD58 | c.700A>G p.M234V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DYSF | c.3655del p.E1219Sfs*42 | Frame Shift Del (DEL) | VAF 33/136 reads (24%) | called by mutect2, varscan2
- NLGN4X | c.1720_1741del p.L574Tfs*20 | Frame Shift Del (DEL) | VAF 21/188 reads (11%) | called by mutect2, pindel
- SELPLG | c.388_418del p.E130Rfs*17 | Frame Shift Del (DEL) | VAF 24/169 reads (14%) | called by mutect2, pindel
- SMYD1 | c.326_327del p.R109Hfs*69 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by pindel, varscan2
- STAT1 | c.1879_1900del p.D627Tfs*31 | Frame Shift Del (DEL) | VAF 16/123 reads (13%) | called by mutect2, pindel
- TBC1D10A | c.109_112del p.E37Sfs*42 | Frame Shift Del (DEL) | VAF 26/100 reads (26%) | called by pindel, varscan2
- APEX1 | c.81G>A p.K27= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs754170368, COSV99164452; called by muse, mutect2, varscan2
- ARFGEF3 | c.933G>A p.A311= | Silent (SNP) | VAF 53/148 reads (36%) | catalogued as rs1052992810, COSV99292723; called by muse, mutect2, varscan2
- ARHGEF11 | c.219G>A p.R73= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs745855825, COSV100809823; called by muse, mutect2, varscan2
- ATP11B | c.2337A>G p.L779= | Silent (SNP) | VAF 58/197 reads (29%) | catalogued as rs147678050, COSV100017610; called by muse, mutect2, varscan2
- CCT8L2 | c.1542C>G p.L514= | Silent (SNP) | VAF 117/367 reads (32%) | catalogued as COSV100742602, COSV63462183; called by muse, mutect2, varscan2
- CHD9 | c.1527T>C p.S509= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as COSV101271975; called by muse, mutect2, varscan2
- COL4A2 | c.1551A>G p.R517= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100847270; called by muse, mutect2, varscan2
- CORO2A | c.1467G>T p.R489= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1477475547, COSV100673988; called by muse, mutect2, varscan2
- CUBN | c.10548T>C p.Y3516= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV100912245; called by muse, mutect2, varscan2
- DNAH9 | c.10362C>T p.T3454= | Silent (SNP) | VAF 45/156 reads (29%) | catalogued as COSV99304774; called by muse, mutect2, varscan2
- DNAJB7 | c.6G>C p.V2= | Silent (SNP) | VAF 12/203 reads (6%) | catalogued as COSV53422473, COSV99344038; called by muse, mutect2
- DNAJC6 | c.1068A>C p.L356= | Silent (SNP) | VAF 88/257 reads (34%) | catalogued as COSV99674290; called by muse, mutect2, varscan2
- EPHA3 | c.1353T>C p.N451= | Silent (SNP) | VAF 82/212 reads (39%) | catalogued as rs770702909, COSV100343732; called by muse, varscan2
- ERCC5 | c.57C>T p.P19= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs1374539446, COSV99958611; called by muse, mutect2, varscan2
- GJB4 | c.222G>C p.V74= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV100258344; called by muse, mutect2, varscan2
- KIAA1109 | c.4827A>T p.P1609= | Silent (SNP) | VAF 72/143 reads (50%) | catalogued as COSV99148284; called by muse, mutect2, varscan2
- KRT75 | c.241C>A p.R81= | Silent (SNP) | VAF 62/199 reads (31%) | catalogued as COSV99359265; called by muse, mutect2, varscan2
- LPL | c.207C>T p.F69= | Silent (SNP) | VAF 74/229 reads (32%) | catalogued as COSV100255404; called by muse, mutect2, varscan2
- LRFN5 | c.1881T>G p.S627= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV99982874; called by muse, mutect2, varscan2
- LSAMP | c.174G>A p.K58= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as COSV100369517; called by muse, mutect2, varscan2
- MUC16 | c.19032C>T p.S6344= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as rs374525892; called by muse, mutect2, varscan2
- MYO7B | c.4228C>A p.R1410= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV101267962; called by muse, mutect2, varscan2
- NME8 | c.1347T>C p.P449= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV99552950; called by muse, mutect2, varscan2
- P2RY4 | c.720C>T p.R240= | Silent (SNP) | VAF 31/50 reads (62%) | catalogued as COSV100996991; called by muse, mutect2, varscan2
- PFKP | c.1245C>T p.V415= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs768110174, COSV101127034; called by muse, mutect2, varscan2
- POP1 | c.459A>G p.R153= | Silent (SNP) | VAF 51/122 reads (42%) | catalogued as rs771415317, COSV100855680; called by muse, mutect2, varscan2
- PRB3 | c.780C>G p.P260= (on ENST00000381842; = p.P302= on NM_006249.5) | Silent (SNP) | VAF 169/964 reads (18%) | catalogued as COSV99685567; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1437C>A p.G479= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as COSV99622622; called by muse, mutect2, varscan2
- RELN | c.4797T>C p.N1599= | Silent (SNP) | VAF 62/197 reads (31%) | catalogued as COSV100632824; called by muse, mutect2, varscan2
- REPS2 | c.708C>G p.P236= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as rs138758958, COSV100380938; called by muse, mutect2, varscan2
- RINL | c.1603C>A p.R535= (on ENST00000591812 / NM_001195833.2; = p.R421= on NM_198445.4) | Silent (SNP) | VAF 48/196 reads (24%) | catalogued as COSV100531036; called by muse, mutect2, varscan2
- RNF213 | c.675C>T p.T225= | Silent (SNP) | VAF 56/203 reads (28%) | catalogued as COSV100173199; called by muse, mutect2, varscan2
- TASP1 | c.552T>C p.P184= | Silent (SNP) | VAF 42/158 reads (27%) | catalogued as COSV100534467; called by muse, varscan2
- TTN | c.68400G>A p.R22800= (on ENST00000591111; = p.R15376= on NM_003319.4) | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as COSV100600194; called by muse, mutect2, varscan2
- UCP1 | c.363A>T p.L121= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as COSV99530159; called by muse, mutect2, varscan2
- USH2A | c.5766G>A p.Q1922= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as rs1278885062, COSV100231051; called by muse, mutect2, varscan2
- VPS37B | c.360C>T p.D120= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV99931802; called by muse, mutect2, varscan2
- ZDHHC19 | c.514C>T p.L172= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as rs754071153, COSV99579448; called by muse, mutect2, varscan2
- ZNF460 | c.597A>C p.P199= | Silent (SNP) | VAF 130/287 reads (45%) | catalogued as COSV100828041; called by muse, mutect2, varscan2
- CCDC30 | c.385-8880G>A | Intron (SNP) | VAF 72/195 reads (37%) | catalogued as rs1253371284, COSV59608927; called by mutect2, varscan2
- FAM155A | c.*2G>T | 3'UTR (SNP) | VAF 25/101 reads (25%) | catalogued as COSV101027155; called by muse, mutect2, varscan2
- PSMB8 | chr6:32844389 G>T | 5'Flank (SNP) | VAF 49/163 reads (30%) | catalogued as COSV100841125; called by muse, mutect2, varscan2
- SLC17A3 | c.304-192G>T | Intron (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100399107; called by muse, mutect2, varscan2
- SNORD115-16 | n.35A>T | RNA (SNP) | VAF 207/756 reads (27%) | called by muse, mutect2, varscan2
- SNORD116-24 | n.63T>A | RNA (SNP) | VAF 117/375 reads (31%) | called by muse, mutect2, varscan2
- VPS26C | chr21:37221350 G>A | 3'Flank (SNP) | VAF 52/136 reads (38%) | called by muse, mutect2, varscan2
